Somatic mutation profile of tumor specimen TCGA-CD-8524-01A (aliquot TCGA-CD-8524-01A-11D-2340-08) from TCGA case TCGA-CD-8524, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 61.5 years (22,445 days).
Specimen TCGA-CD-8524-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d59821f6-c359-4916-b86b-4913e603e3a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-8524-10A (Blood Derived Normal), aliquot TCGA-CD-8524-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56885d37-fb46-4772-a233-73943a37acc9

The open-access MAF lists 155 somatic variants for this specimen: 119 protein-altering or splice-affecting, 32 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 32, Nonsense Mutation 11, Frame Shift Del 3, RNA 2, Intron 2, Splice Site 2, Frame Shift Ins 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BNC2 | c.1723A>C p.S575R | Missense Mutation (SNP) | VAF 36/71 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs1374823674, COSV66140362; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACAN | c.5692C>T p.P1898S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs761003367, COSV61359055; called by muse, mutect2, varscan2
- ADCY10 | c.1370G>T p.G457V | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63240011; called by muse, mutect2
- ADRA1A | c.818C>T p.T273M | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1218686921, COSV52361833; called by muse, mutect2, varscan2
- AOC1 | c.1915C>T p.H639Y | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV62868138; called by muse, mutect2, varscan2
- APBA1 | c.634G>A p.G212S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.987); catalogued as rs763263675, COSV55225948; called by muse, mutect2, varscan2
- ASCC3 | c.4300G>T p.V1434F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV64974247; called by muse, mutect2, varscan2
- ASTN1 | c.1805G>A p.R602H | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs375093597; called by muse, mutect2
- ASTN2 | c.579G>T p.E193D | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.82); catalogued as rs1330936382, COSV57769827; called by muse, mutect2, varscan2
- ATAD2 | c.1366A>G p.K456E | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV54879794; called by muse, mutect2, varscan2
- ATRX | c.826T>G p.L276V | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV64874798; called by muse, mutect2, varscan2
- BCO2 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.088); catalogued as COSV63063072; called by muse, mutect2, varscan2
- BNC2 | c.2246G>A p.S749N | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV66144932; called by muse, mutect2, varscan2
- BPNT2 | c.883_884insC p.Y295Sfs*11 | Frame Shift Ins (INS) | VAF 7/33 reads (21%) | catalogued as COSV99388911; called by mutect2, pindel, varscan2
- C8orf34 | c.1279T>C p.S427P | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV57401409, COSV57414606; called by muse, mutect2, varscan2
- CALML3 | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); catalogued as rs184719998, COSV59449258; called by muse, mutect2, varscan2
- CCER1 | c.1128G>T p.E376D | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as rs528219668, COSV62646491, COSV62648654; called by muse, mutect2, varscan2
- CLDN22 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60109270; called by muse, mutect2
- COL25A1 | c.709-1G>A p.X237_splice | Splice Site (SNP) | VAF 8/34 reads (24%) | catalogued as COSV67649142; called by muse, mutect2, varscan2
- CPLX1 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV58375716; called by muse, mutect2
- CSMD2 | c.8707C>T p.R2903* | Nonsense Mutation (SNP) | VAF 20/42 reads (48%) | catalogued as COSV53902072; called by muse, mutect2, varscan2
- CSNK1D | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53923953; called by muse, mutect2, varscan2
- CTSO | c.877A>G p.S293G | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.309); catalogued as COSV70808893, COSV70809027; called by muse, mutect2, varscan2
- CYTH1 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as COSV63119844; called by muse, mutect2, varscan2
- DMD | c.2900T>G p.L967R | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs766400327, COSV63747968; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAJC3 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV65131170; called by muse, mutect2, varscan2
- DUSP14 | c.49C>T p.R17W | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs781411697; called by muse, mutect2, varscan2
- EDNRB | c.1052A>C p.Q351P (on ENST00000377211 / NM_001201397.1; = p.Q261P on NM_000115.5) | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); catalogued as COSV57521335; called by muse, mutect2, varscan2
- ELOA2 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.165); catalogued as COSV55297292; called by muse, mutect2, varscan2
- ENG | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs763508329, COSV61227176; ClinVar: uncertain significance; called by muse, varscan2
- ERBB4 | c.3394C>T p.P1132S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61479967; called by muse, mutect2, varscan2
- FAM13A | c.497G>A p.C166Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as rs1167901697, COSV51996914, COSV52000860; called by muse, mutect2, varscan2
- FZD1 | c.1423G>A p.G475R | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55309963; called by muse, mutect2, varscan2
- GALNT13 | c.945G>A p.W315* | Nonsense Mutation (SNP) | VAF 24/76 reads (32%) | catalogued as COSV67217230; called by muse, mutect2, varscan2
- GDF2 | c.1207G>A p.V403I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs367957332; called by muse, mutect2, varscan2
- GRM2 | c.1355G>A p.R452H | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as rs748577145, COSV56584011; called by muse, mutect2, varscan2
- HIVEP2 | c.2898C>G p.S966R | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50008872; called by muse, mutect2, varscan2
- IGFBP6 | c.643G>A p.V215M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56857248; called by muse, mutect2, varscan2
- JPH3 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.062); catalogued as rs142136496; called by muse, mutect2, varscan2
- KCNN2 | c.516C>A p.C172* (on ENST00000264773; = p.C384* on NM_021614.4) | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV53287013; called by muse, mutect2, varscan2
- KCNT1 | c.3489C>T p.D1163= (on ENST00000488444; = p.D1168= on NM_020822.3) | Splice Region (SNP) | VAF 14/68 reads (21%) | catalogued as rs761504279, COSV53699691; ClinVar: likely benign; called by muse, mutect2, varscan2
- KHDRBS2 | c.489C>A p.Y163* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as rs1261194503, COSV99832210; called by muse, mutect2, varscan2
- KLHL30 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs745649884, COSV59975212; called by muse, mutect2, varscan2
- LAMA3 | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs539451824, COSV58066561; called by muse, varscan2
- LILRA5 | c.876C>G p.S292R | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1301475072, COSV100006826; called by muse, mutect2
- LRP1B | c.9280G>A p.V3094I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV101257936, COSV67206765; called by muse, mutect2, varscan2
- MAP3K4 | c.3010G>A p.A1004T | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs1404985047, COSV62329854, COSV62331269; called by muse, mutect2, varscan2
- MAPK8 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV64408785; called by muse, mutect2, varscan2
- MEGF10 | c.1331C>G p.P444R | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV57248001; called by muse, mutect2
- MMP7 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs765986644, COSV52771302; called by muse, mutect2, varscan2
- MYH1 | c.4853T>C p.L1618P | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as rs1354093914, COSV56846676; called by muse, mutect2
- MYH10 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as rs751139947, COSV52598890; called by muse, varscan2
- NAV3 | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs768491749, COSV57074223; called by muse, mutect2, varscan2
- NAV3 | c.3113C>A p.P1038H | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57074243; called by muse, mutect2, varscan2
- NDUFS5 | c.278C>G p.T93S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV65892296, COSV65892349; called by muse, mutect2, varscan2
- NEIL3 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1263191299, COSV52809825; called by muse, mutect2, varscan2
- NEURL2 | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV51941700; called by muse, mutect2, varscan2
- NTSR2 | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.638); catalogued as rs139725500; called by muse, mutect2, varscan2
- NUDT14 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.049); catalogued as rs761912638, COSV59650201; called by muse, mutect2, varscan2
- NUP85 | c.1117T>C p.F373L | Missense Mutation (SNP) | VAF 56/101 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.773); catalogued as COSV55463607; called by muse, mutect2, varscan2
- NUTM2D | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs773866267, COSV67746199; called by muse, mutect2, varscan2
- OR10T2 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as COSV57780856, COSV57781915; called by muse, mutect2, varscan2
- OR2M3 | c.769T>G p.F257V | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV71758988; called by muse, mutect2, varscan2
- OR2W1 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV65851523; called by muse, mutect2, varscan2
- OTOGL | c.518C>T p.S173L (on ENST00000547103; = p.S164L on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs377611164; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH10 | c.1948C>A p.P650T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.899); catalogued as COSV52091845; called by muse, mutect2, varscan2
- PCDHAC1 | c.1627T>G p.L543V | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV53845822; called by muse, mutect2, varscan2
- PCDHB2 | c.761C>T p.P254L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.02); catalogued as COSV52031592; called by muse, mutect2, varscan2
- PEX13 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs903847229, COSV54369733; called by muse, mutect2, varscan2
- PHEX | c.1942G>T p.G648* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | catalogued as CM157367, COSV65074911; called by muse, mutect2, varscan2
- PKHD1 | c.2330C>T p.T777M | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as rs564240823, COSV61859047; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR2B | c.1250T>A p.I417N | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.197); catalogued as COSV58899820; called by muse, mutect2, varscan2
- POU4F3 | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV57942462; called by muse, mutect2, varscan2
- RCAN2 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs556179069, COSV57815822; called by muse, mutect2, varscan2
- RRP36 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 9/65 reads (14%) | catalogued as rs575586322, COSV55064065; called by muse, mutect2, varscan2
- RYR2 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs754259295, COSV63678919; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN1A | c.5771G>A p.R1924H (on ENST00000303395 / NM_001202435.3; = p.R1913H on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs3749029, COSV57663941, COSV57666596; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN5A | c.802G>A p.G268S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750990576, COSV61121407; called by muse, mutect2, varscan2
- SDCBP | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs144425100, COSV99486582; called by muse, mutect2, varscan2
- SDK1 | c.4487G>A p.R1496Q | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as rs141114121; called by muse, mutect2
- SEC24B | c.2059T>A p.S687T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.421); catalogued as COSV54497905; called by muse, mutect2, varscan2
- SENP7 | c.2079A>C p.E693D | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV58610700, COSV58613138; called by muse, mutect2, varscan2
- SETDB1 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.613); catalogued as rs767529609, COSV54983937; called by muse, mutect2, varscan2
- SETX | c.1950G>T p.M650I | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV56380363, COSV56383058; called by muse, mutect2
- SFMBT1 | c.1645G>A p.A549T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56253293; called by muse, mutect2, varscan2
- SGCG | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54558764; called by muse, mutect2, varscan2
- SHC1 | c.734C>A p.A245D (on ENST00000368445 / NM_183001.5; = p.A135D on NM_003029.5) | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as COSV100820992; called by muse, mutect2
- SNTG1 | c.1036A>T p.K346* | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as COSV52437724; called by muse, mutect2, varscan2
- SNX17 | c.955C>T p.R319* | Nonsense Mutation (SNP) | VAF 7/66 reads (11%) | catalogued as rs776030359, COSV52007359; called by muse, mutect2, varscan2
- STAB2 | c.3148T>C p.W1050R | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101185743; called by muse, mutect2
- STX11 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as COSV100845476, COSV62448952; called by muse, mutect2, varscan2
- SYT6 | c.270C>G p.N90K (on ENST00000610222 / NM_001366225.1; = p.N5K on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV65773413; called by muse, mutect2, varscan2
- TENM1 | c.274C>A p.H92N | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT tolerated, low confidence (0.75); PolyPhen possibly damaging (0.782); catalogued as COSV64429933; called by muse, mutect2, varscan2
- THBS1 | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs369659280; called by muse, mutect2, varscan2
- TLR1 | c.1114A>G p.T372A | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV58303991; called by muse, mutect2, varscan2
- TLR4 | c.640C>G p.P214A (on ENST00000355622 / NM_138554.5; = p.P174A on NM_003266.4) | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.174); catalogued as COSV62922774; called by muse, mutect2, varscan2
- TMEM30A | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57875033; called by muse, mutect2, varscan2
- TRIM55 | c.294C>A p.N98K | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760433737, COSV52545383; called by muse, mutect2, varscan2
- TRPC5 | c.321A>C p.E107D | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV53288279; called by muse, mutect2, varscan2
- TTN | c.42457G>A p.V14153I (on ENST00000591111; = p.V6729I on NM_003319.4) | Missense Mutation (SNP) | VAF 11/135 reads (8%) | PolyPhen benign (0.001); catalogued as rs727504878, COSV59991854; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- TTN | c.6043G>A p.A2015T (on ENST00000591111; = p.A1969T on NM_003319.4) | Missense Mutation (SNP) | VAF 50/140 reads (36%) | PolyPhen possibly damaging (0.777); catalogued as rs776534823, COSV59991879; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUSC3 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | catalogued as COSV65880324, COSV65885235; called by muse, mutect2, varscan2
- TYR | c.1086G>A p.M362I | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV54473581; called by muse, mutect2, varscan2
- UGT1A10 | c.422C>A p.S141Y | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as COSV60836280; called by muse, mutect2, varscan2
- UNC13D | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs560126604, COSV52884065; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC5D | c.1712T>A p.I571N | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV54785747; called by muse, mutect2
- VPS51 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs771038781, COSV54206853; called by muse, mutect2
- ZBTB46 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.176); catalogued as rs751613846, COSV55508803; called by muse, mutect2, varscan2
- ZCCHC24 | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768289331, COSV64886471; called by muse, mutect2, varscan2
- ZMAT4 | c.193-1G>A p.X65_splice | Splice Site (SNP) | VAF 9/32 reads (28%) | catalogued as COSV52695904; called by muse, mutect2
- ZNF284 | c.1332G>T p.L444F | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV69690872; called by muse, mutect2, varscan2
- ZNF446 | c.392C>G p.T131R | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as COSV52180220; called by muse, mutect2, varscan2
- ENPP6 | c.290_294dup p.T99Pfs*16 | Frame Shift Ins (INS) | VAF 5/41 reads (12%) | called by mutect2, varscan2
- IQCH | c.1270del p.Q424Rfs*34 | Frame Shift Del (DEL) | VAF 34/118 reads (29%) | called by mutect2, pindel, varscan2
- OR4C12 | c.909del p.V304* | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | called by mutect2, pindel, varscan2
- PRAG1 | c.1408_1414del p.V470Pfs*19 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | called by mutect2, pindel
- PSME4 | c.3975_3983del p.F1325_S1327del | In Frame Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- TBC1D3F | c.29G>A p.W10* | Nonsense Mutation (SNP) | VAF 58/678 reads (9%) | called by muse, mutect2
- ACTL9 | c.543G>A p.S181= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs782083842, COSV61005467; called by muse, mutect2, varscan2
- CSMD1 | c.765A>G p.L255= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs748097214, COSV68192696; called by muse, mutect2
- FIG4 | c.312C>G p.G104= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as COSV57786887; called by muse, mutect2, varscan2
- GPR179 | c.894C>T p.L298= (on ENST00000621958; = p.L297= on NM_001004334.4) | Silent (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- JHY | c.1305C>G p.L435= | Silent (SNP) | VAF 5/84 reads (6%) | catalogued as COSV57080461; called by muse, mutect2
- KIR2DL4 | c.726C>A p.P242= (on ENST00000396284; = p.P203= on NM_001080770.2) | Silent (SNP) | VAF 30/294 reads (10%) | catalogued as rs1049277022; called by muse, varscan2
- LTBP1 | c.4527G>A p.P1509= (on ENST00000404816 / NM_206943.4; = p.P1183= on NM_000627.4) | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs769364870, COSV55378259; called by muse, mutect2, varscan2
- MUC16 | c.38133G>A p.K12711= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs987775673, COSV67459688; called by muse, mutect2, varscan2
- MYH3 | c.1641C>T p.T547= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as COSV56863545; called by muse, mutect2, varscan2
- NDNF | c.129G>A p.S43= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs748245904, COSV65632397; called by muse, mutect2, varscan2
- NR6A1 | c.849A>G p.L283= (on ENST00000487099 / NM_033334.4; = p.L278= on NM_001489.5) | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV60632315; called by muse, mutect2, varscan2
- NRG3 | c.564G>A p.A188= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV64555944; called by muse, mutect2, varscan2
- OR4C13 | c.660G>T p.L220= | Silent (SNP) | VAF 14/133 reads (11%) | catalogued as COSV73648717; called by muse, mutect2, varscan2
- PCDH10 | c.1248T>A p.V416= | Silent (SNP) | VAF 28/185 reads (15%) | catalogued as COSV52091820; called by muse, mutect2, varscan2
- PCDHA12 | c.1533C>T p.H511= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as COSV56493435; called by muse, mutect2, varscan2
- PGBD5 | c.792G>A p.A264= (on ENST00000525115; = p.A333= on NM_001258311.2) | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs746541408, COSV58411249; called by muse, mutect2, varscan2
- PPFIBP1 | c.2475G>A p.A825= (on ENST00000318304 / NM_177444.3; = p.A819= on NM_003622.4) | Silent (SNP) | VAF 905/1098 reads (82%) | catalogued as rs746681298, COSV57290047, COSV99945708; called by muse, mutect2, varscan2
- RYR2 | c.12435C>A p.I4145= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV63671059, COSV63678927; called by muse, mutect2, varscan2
- SBK2 | c.903C>T p.D301= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs775484962, COSV60013897; called by muse, mutect2, varscan2
- SEC61A1 | c.858G>A p.T286= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as rs763828160, COSV54576782; called by muse, varscan2
- SETDB1 | c.171C>A p.R57= | Silent (SNP) | VAF 19/159 reads (12%) | catalogued as COSV54988020, COSV99644101; called by muse, mutect2, varscan2
- SMARCB1 | c.237C>T p.H79= | Silent (SNP) | VAF 9/123 reads (7%) | catalogued as rs200394488, COSV99575476; ClinVar: likely benign; called by muse, mutect2
- SOGA3 | c.2709C>T p.A903= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as rs1363404082, COSV64109508; called by muse, mutect2
- SORCS1 | c.462G>T p.R154= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV53857634; called by muse, mutect2, varscan2
- TGFBI | c.1479G>A p.T493= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1003603883, COSV59350874; called by muse, mutect2, varscan2
- TMEM68 | c.456C>T p.C152= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as rs1450855021; called by muse, mutect2
- TRPC3 | c.654C>T p.D218= (on ENST00000379645 / NM_001366479.2; = p.D145= on NM_003305.2) | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as rs766293867, COSV53374224; called by muse, mutect2, varscan2
- TTN | c.47649G>C p.L15883= (on ENST00000591111; = p.L8459= on NM_003319.4) | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV59991826; called by muse, mutect2, varscan2
- VSIR | c.351C>T p.H117= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs750196284, COSV56457729; called by muse, mutect2, varscan2
- XKR9 | c.784T>C p.L262= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV104435404, COSV68772803; called by muse, mutect2, varscan2
- ZNF613 | c.1704T>G p.S568= (on ENST00000293471 / NM_001031721.4; = p.S532= on NM_024840.4) | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV53271516, COSV53272217; called by muse, mutect2
- ZNF750 | c.1308G>A p.K436= | Silent (SNP) | VAF 25/67 reads (37%) | catalogued as COSV53959861; called by muse, mutect2, varscan2
- FLAD1 | c.1555-140_1555-135del | Intron (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel, varscan2
- MDS2 | n.307C>A | RNA (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- RBPMS2 | c.88-10859C>T | Intron (SNP) | VAF 9/65 reads (14%) | catalogued as rs1342874420, COSV55603274; called by muse, mutect2, varscan2
- SNORD115-18 | n.24T>G | RNA (SNP) | VAF 30/227 reads (13%) | called by muse, mutect2, varscan2
